Gene-level copy-number profile of tumor specimen HTMCP-03-06-02213-01A from CGCI case HTMCP-03-06-02213, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02213-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ddd5d201-2c65-4008-b630-0a9a00d42058.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02213-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/f2576c27-8caf-4898-b17c-cd31a2aa3a20

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 5,912; copy number 2: 41,635; copy number 3: 9,169; copy number 4: 1,443; copy number 5: 92; copy number 6: 10; copy number 7: 26; copy number 8: 3; copy number 9: 8; copy number 11: 39; copy number 29: 1; copy number 32: 19; copy number 52: 3.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:212,832,161–212,926,336, 4 genes (within-gene range 0–1): PCED1CP, AC108066.1, MIR4776-1, MIR4776-2.
- chr4:181,237,358–181,265,145, 2 genes: AC019235.1, LINC02500.
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.
- chr20:10,435,305–12,381,255, 24 genes: SLX4IP, AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2.
- chr20:14,547,184–14,758,056, 3 genes (within-gene range 0–1): RNF11P2, MACROD2-IT1, RPS10P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 201 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:84,423,528–86,492,716, 66 genes, copy number 7–29 (broad region; genes not listed).
- chr2:161,136,908–161,428,774, 10 genes, copy number 6 (within-gene range 3–6): TANK, AC009299.2, LINC01806, AC009299.1, PSMD14, MXRA7P1, RNA5SP108, TBR1, AC009487.1, AC009487.2.
- chr10:4,871,901–7,118,469, 63 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:100,687,288–102,727,050, 33 genes, copy number 8–52 (within-gene range 3–52): ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8.
- chr14:22,202,583–22,479,582, 28 genes, copy number 5: TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.

Autosomal genes at a single copy (total copy number 1): 5,906. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
